Surgical pathology report (de-identified scan), TCGA case TCGA-55-6985, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-6985-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Specimen(s) Received

A: Pulmonary ligament node level 9
B: P A window node
C: Hilar lymph node
D: Lung left upper lobe

Pathologic Diagnosis

- A. Pulmonary ligament node level 9: One lymph node negative for malignancy.
B. P A window node: Multiple (4) lymph nodes negative for malignancy.
C. Hilar lymph node: Multiple (3) lymph nodes negative for malignancy.

D. Lung left upper lobe:

Histologic Type:	Adenocarcinoma
Histologic Grade:	Moderately differentiated
Tumor Size:	Greatest dimension: 2.0 cm
Specimen Type:	Lobectomy
Extent of Invasion:	Tumor invades the following structures: Visceral pleura
Regional Lymph Nodes:	Number involved: 0 Number examined: 7
Distant Metastasis:	Cannot be assessed
Margins:	Margins uninvolved by invasive carcinoma
Lymphovascular Invasion:	Absent
Venous Invasion:	Absent
Arterial Invasion:	Absent

pT2pN0pMX

Primary Pathologist
Electronically Signed Out by:

Clinical History

Cancer, left upper lobe lung.

[page 2 of 2]
Gross Description

"A" - Received in formalin labeled "pulmonary lymph node, level 9" is a single tan lymph node which contains anthracotic pigment and measures 2 x 1 x 0.4 cm. The specimen is bisected and submitted in "A1".

"B" - Received in formalin labeled "PA window node level 5" are four separate fragments of tan tissue resembling lymph nodes. The tissues range in size from 0.5 up to 1 cm in greatest dimension. The large lymph node is inked black and bisected.

"C" - Received in formalin labeled "hilar lymph nodes" are three tissue fragments resembling lymph nodes. These are tan-to-gray and range in size from 0.5 up to 2 cm. The largest lymph node is bisected and submitted as "C1". "C2" contains two lymph nodes, one bisected and inked black; the other is submitted intact.

"D" - Received in formalin labeled "left upper lobe" is a left upper lobe of lung weighing 136 grams and measuring 18 x 7 x 2 cm. There is a bronchial stump which measures 1.5 x 0.3 cm. Blood is present within the lumen. There is a 1.5 x 2 x 1 cm tan-to-gray mass present in the central portion of the specimen. The mass appears close but does not penetrate the pleural surface. The mass is located 4 cm away from the bronchial resection margin and 6 cm away from the apical portion of the lung. The pleural surface is pink-to-tan with some anthracotic pigment present. The pleural surface overlying the tumor is inked black. The remaining lung parenchyma is red-to-tan. No additional masses or nodules are seen. Sections are submitted as follows: "D1" - bronchial and vascular resection margins; "D2"- "D5" - tumor entirely submitted with adjacent pleura; "D7" - multiple peribronchial lymph nodes submitted intact.

Microscopic Description

Microscopic examination has been performed on all slides. The pathologic diagnosis encompasses the essential microscopic findings of this case.

Source: NCI Genomic Data Commons file 1347c8b7-565d-4c20-be8c-cbfe59b60b4f (TCGA-55-6985.C6FC0473-B67A-47F1-81F2-ECC0CBC9CC5F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).